Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6225, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6225-01A (Primary Tumor).

[page 1 of 3]
Specimen(s) Received

1. Lymph-Node: LEFT NECK LEVEL 2
2. Oral Cavity: biopsy left palate
3. Oral Cavity: left tongue base
4. Oral Cavity: deep margin of tongue
5. Oral Cavity: revise inferior margin of tongue
6. Neck: left neck contents
7. Oral Cavity: left tongue, left floor mouth and palate

Diagnosis

1. Left neck level II.
Adipose tissue with no pathologic changes.
No lymph nodes present.
2. Biopsy left palate.
Squamous mucosa with no pathologic changes.
Negative for tumor.
3. Left tongue base.
Negative for tumor.
4. Deep margin of tongue.
Negative for tumor.
5. Revise inferior margin of tongue.
Negative for tumor.
6. Left neck contents.
Twenty-five lymph nodes negative for tumor (0/25).
Submandibular gland with extensive atrophy consistent with prior radiotherapy.
7. Oral Cavity; left tongue, left floor mouth and palate.
Squamous cell carcinoma, moderately differentiated.

[page 2 of 3]
- a. Maximum tumor diameter 4.9 cm.
- b. Tumor thickness 2.9 cm.
- c. Extensive perineural invasion.
- d. No lymphovascular invasion.
- e. Extensive clear cell change.
- f. Tumor is close (0.2) to the deep medial soft tissue margin. Remaining margins negative for tumor.

Electronically

Clinical History

oral cancer

Gross Description

1. The specimen is labeled with the patient's name and as "Lymph-Node: Left neck level II". It consists of a piece of fibroadipose tissue that measures 1.7 x 1.7 x 0.2 cm. No lymph nodes are grossly identified.

1A specimen in toto

2. The specimen is labeled with the patient's name and as "Oral Cavity: Biopsy left palate". It consists of a fragment of tissue measuring 1.4 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.

2A frozen section control

3. The specimen is labeled with the patient's name and as "Oral Cavity: Left tongue base". It consists of a fragment of tissue measuring 1.6 x 1.0 x 0.4 cm. The specimen is submitted in toto for frozen section.

3A frozen section control

4. The specimen is labeled with the patient's name and as "Oral Cavity: Deep margin of tongue". It consists of a fragment of tissue measuring 1.5 x 1.0 x 0.3 cm. The specimen is submitted in toto for frozen section.

4A frozen section control

5. The specimen is labeled with the patient's name and as "Oral Cavity: Revised inferior margin of tongue". It consists of an unoriented portion of tongue measuring 2.7 x 2.7 x 1.2 cm.

5A-5D specimen serially sectioned and submitted in toto

6. The specimen is labeled with the patient's name and as "Neck: left neck contents". It consists of an unoriented left neck dissection with overall dimensions of 11.0 x 7.5 x 2.7 cm. The sternocleidomastoid is unremarkable and measures 4.8 x 2.0 x 1.0 cm. The submandibular gland measures 4.5 x 3.0 x 2.0 cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 1.6 cm are identified. Representative sections are submitted as follows:

6A submandibular gland

6B-6D multiple lymph nodes per block

6E two lymph nodes

6F-6K one lymph node, per block

6L multiple lymph nodes

7. The specimen is labeled the patient's name and as "Oral Cavity: Left tongue, left floor of mouth and palate". It consists of an unoriented portion of left tongue with attached floor of

[page 3 of 3]
mouth/sublingual gland/soft palate with overall dimension of 5.5 cm SI x 4.5 cm ML x 11.5 cm AP. The sublingual gland measures 1.7 cm SI x 1.4 cm ML x 1.7 cm AP. There is an ulcerated tumor involving the left lateral surface of the tongue/floor of mouth. The tumor measures 2.9 cm SI x 3.2 cm ML x 4.9 cm AP. The cut surface of the tumor appears white, solid and firm. It is located: at the supero-lateral margin, 3.2 cm from the anterior tip of tongue, 3.0 cm from the posterior tongue margin, 0.2 cm from the medial margin, 0.3 cm from the inferior/deep margin, 0.3 cm from the lateral floor of mouth margin, 0.2 cm from the sublingual gland and 0.4 cm from the supero-lateral soft palate margin. All the margins of the specimen are painted black. Three pieces of tumor and normal tongue are taken for the tissue bank. Representative sections are submitted.

- 7A anterior tip of tongue
- 7B tumor with inferior/deep margin
- 7C tumor with medial margin
- 7D tumor with sublingual gland
- 7E tumor with lateral floor of mouth margin
- 7F tumor at supero-lateral surface of tongue
- 7G-7H tumor
- 7I posterior tongue margin
- 7J tongue mucosa with hair-like projections

Quick Section Diagnosis

- 2. Biopsy Left Palate, quick section: Negative for malignancy
- 3. Left tongue base, quick section: Negative for malignancy
- 4. Deep Margin of Tongue, quick section: Negative for malignancy

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c6a17d9c-0f00-4929-9d82-a16117c04c71 (TCGA-CQ-6225.398DA2C7-552E-4015-9B58-4F8ECCE17261.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).